Somatic mutation profile of tumor specimen TCGA-AG-A01L-01A (aliquot TCGA-AG-A01L-01A-01W-A00K-09) from TCGA case TCGA-AG-A01L, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 58.5 years (21,369 days).
Specimen TCGA-AG-A01L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36d375f5-2e48-4b5e-b0b6-3956849cda94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A01L-10A (Blood Derived Normal), aliquot TCGA-AG-A01L-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d039fcaa-2814-447f-a790-edb0eff81981

The open-access MAF lists 66 somatic variants for this specimen: 52 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Nonsense Mutation 9, Frame Shift Ins 2, Intron 1, Splice Site 1, Frame Shift Del 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 110/221 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 32/48 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1B | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231420; called by muse, mutect2, varscan2
- ASAP1 | c.3286G>A p.V1096I | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs764209195, COSV100727278, COSV63048856; called by muse, mutect2, varscan2
- ATP13A5 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as COSV60870465; called by muse, mutect2, varscan2
- CCDC185 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV64821970; called by muse, mutect2
- CEP89 | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs767672127; called by muse, mutect2
- CHD2 | c.4220C>A p.S1407Y | Missense Mutation (SNP) | VAF 106/394 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as rs780455269; called by muse, mutect2, varscan2
- CSMD1 | c.5806G>A p.D1936N (on ENST00000520002; = p.D1935N on NM_033225.6) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs867860501, COSV59386950; called by muse, mutect2, varscan2
- EFCAB6 | c.4369G>A p.A1457T | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.904); catalogued as rs751667777; called by muse, mutect2, varscan2
- ELOA2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.38); PolyPhen benign (0.165); catalogued as COSV55297292; called by muse, mutect2, varscan2
- FSCB | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 41/395 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV61219619; called by muse, mutect2, varscan2
- GBP1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as rs779097744, COSV65082905; called by muse, mutect2, varscan2
- HARS2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764476456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNG1 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV65370515; called by muse, varscan2
- KCNQ3 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as rs1289108911, COSV66482745; called by muse, mutect2, varscan2
- KRTAP19-5 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs142713888; called by muse, mutect2, varscan2
- MAGI2 | c.2503G>A p.G835S | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs762040290, COSV62631468; called by muse, mutect2, varscan2
- OSMR | c.1957C>T p.Q653* | Nonsense Mutation (SNP) | VAF 156/409 reads (38%) | catalogued as rs778570517, COSV57081288; called by muse, mutect2, varscan2
- PCDH10 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52104357; called by muse, mutect2, varscan2
- PCDHGB2 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV53950376; called by muse, mutect2, varscan2
- PDZRN3 | c.2887G>A p.A963T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as rs150622040; called by muse, mutect2, varscan2
- PHLDB1 | c.1246C>G p.L416V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV61882011; called by muse, mutect2, varscan2
- PLD2 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 59/89 reads (66%) | catalogued as rs752087731; called by muse, mutect2, varscan2
- PLP1 | c.137T>A p.L46Q | Missense Mutation (SNP) | VAF 138/167 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM991053, CM993196; called by muse, mutect2, varscan2
- PRDM9 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 84/282 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57001967; called by muse, mutect2, varscan2
- SCML4 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs769590136, COSV64636916; called by muse, mutect2, varscan2
- SEMA5B | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs557492984, COSV52105761; called by muse, mutect2, varscan2
- SPRR2E | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 237/522 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64203831, COSV64204017; called by muse, varscan2
- SV2B | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs143979505; called by muse, mutect2, varscan2
- SYNE3 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs112493785; called by muse, mutect2, varscan2
- TAF3 | c.2020del p.V674Sfs*23 | Frame Shift Del (DEL) | VAF 48/239 reads (20%) | catalogued as COSV100719944; called by mutect2, pindel, varscan2
- TNRC6B | c.2554C>T p.R852* | Nonsense Mutation (SNP) | VAF 64/91 reads (70%) | catalogued as COSV57294963; called by muse, mutect2, varscan2
- VEGFC | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs868250788, COSV54599564; called by muse, mutect2, varscan2
- WIPF1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV55812013; called by muse, mutect2, varscan2
- ZNF408 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1160126418, COSV61239400; called by muse, mutect2, varscan2
- ZNF793 | c.445A>T p.N149Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV71325201; called by muse, mutect2, varscan2
- ZXDA | c.1655A>C p.K552T | Missense Mutation (SNP) | VAF 51/70 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV62388933; called by muse, mutect2, varscan2
- ACVR1B | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 86/246 reads (35%) | called by muse, mutect2, varscan2
- ANGPT1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APC | c.2507dup p.S837Ifs*7 | Frame Shift Ins (INS) | VAF 67/128 reads (52%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- CHAMP1 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 299/567 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHAMP1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 294/557 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXW7 | c.955_985+4del p.X319_splice (on ENST00000281708 / NM_001349798.2; = p.X239_splice on NM_018315.5) | Splice Site (DEL) | VAF 29/142 reads (20%) | called by mutect2, pindel, varscan2
- FRMPD1 | c.2351dup p.S785Vfs*19 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- FRMPD3 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.147); called by muse, mutect2
- MYH7 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PPFIA1 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 171/331 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PRAMEF20 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 224/921 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCML2 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- VWA7 | c.1577A>G p.Q526R | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GNT7 | c.249C>T p.D83= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs992751419, COSV55007663; called by muse, mutect2, varscan2
- CCL3L3 | c.201C>G p.T67= | Silent (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- CREBBP | c.903G>A p.Q301= | Silent (SNP) | VAF 181/451 reads (40%) | catalogued as COSV52113316; called by muse, varscan2
- EEF1AKMT1 | c.468C>T p.T156= | Silent (SNP) | VAF 88/130 reads (68%) | catalogued as COSV101236926; called by muse, mutect2, varscan2
- EPHA10 | c.813C>T p.C271= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV57627367; called by muse, varscan2
- GABRR1 | c.210G>A p.S70= | Silent (SNP) | VAF 164/339 reads (48%) | catalogued as rs371490411; called by muse, mutect2, varscan2
- H4C4 | c.240G>A p.K80= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as rs757232898, COSV61590752; called by muse, mutect2, varscan2
- INHBB | c.672C>T p.S224= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs777437637, COSV54679257; called by muse, mutect2, varscan2
- MTR | c.1311C>T p.S437= | Silent (SNP) | VAF 77/271 reads (28%) | catalogued as rs777192214, COSV63966515; called by muse, mutect2, varscan2
- PTPN13 | c.6667T>C p.L2223= (on ENST00000411767 / NM_080683.3; = p.L2204= on NM_006264.3) | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV57418136; called by muse, mutect2, varscan2
- PYDC2 | c.189C>T p.S63= | Silent (SNP) | VAF 117/285 reads (41%) | catalogued as COSV72921498; called by muse, mutect2, varscan2
- TET1 | c.1285T>C p.L429= | Silent (SNP) | VAF 82/162 reads (51%) | called by muse, mutect2, varscan2
- RUSC1 | c.-86-334G>A | Intron (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- Unknown | chr21:16071127 C>T | IGR (SNP) | VAF 158/332 reads (48%) | catalogued as rs997997040; called by muse, mutect2, varscan2
